Somatic mutation profile of tumor specimen TCGA-CM-5344-01A (aliquot TCGA-CM-5344-01A-21D-1719-10) from TCGA case TCGA-CM-5344, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 39.5 years (14,426 days).
Specimen TCGA-CM-5344-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdb4c1a1-0e34-4c63-a4d9-4f8e0efb6bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5344-10A (Blood Derived Normal), aliquot TCGA-CM-5344-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9265a913-d5ef-4abc-8ae6-e3a959cdc166

The open-access MAF lists 68 somatic variants for this specimen: 47 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 41, Silent 21, Frame Shift Del 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7444C>T p.R2482* (on ENST00000272895 / NM_173076.3; = p.R2164* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 29/179 reads (16%) | catalogued as rs199503269, CM073950, COSV55978292; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.1185G>T p.Q395H (on ENST00000295851 / NM_001375719.1; = p.Q328H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53696633, COSV99651623; called by muse, mutect2, varscan2
- ADIG | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100972533; called by muse, varscan2
- ALDH3A1 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774092621, COSV56734642; called by muse, mutect2, varscan2
- APC | c.4108A>T p.K1370* | Nonsense Mutation (SNP) | VAF 77/134 reads (57%) | catalogued as CM920054, COSV57335316; called by muse, mutect2, varscan2
- ARHGEF28 | c.3886G>A p.V1296M | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as rs368673332; called by muse, mutect2, varscan2
- BEND5 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 268/523 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.166); catalogued as COSV65718919; called by muse, mutect2, varscan2
- BOD1L1 | c.4510G>C p.D1504H | Missense Mutation (SNP) | VAF 99/397 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV50083090; called by muse, mutect2, varscan2
- C12orf42 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.906); catalogued as COSV59387595, COSV59391752; called by muse, mutect2, varscan2
- CEP350 | c.2857A>G p.K953E | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV62610486; called by muse, mutect2, varscan2
- CFAP100 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs142359829; called by muse, mutect2, varscan2
- DMXL1 | c.6344A>T p.N2115I | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60722406; called by muse, mutect2, varscan2
- DNAH11 | c.6118C>T p.R2040C | Missense Mutation (SNP) | VAF 237/702 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs199772877; called by muse, mutect2, varscan2
- FRMPD1 | c.3933G>C p.R1311S | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs748281395, COSV100899489; called by muse, mutect2, varscan2
- IRX1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs1447435029, COSV57362890; called by muse, mutect2, varscan2
- KCNG1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs1220620817, COSV100857042; called by muse, mutect2
- KMT2C | c.13750C>T p.R4584W | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747850540, COSV51428250; called by muse, mutect2, varscan2
- KRT16 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56970028; called by muse, mutect2, varscan2
- KRT4 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs372301476; called by muse, mutect2, varscan2
- KRTAP3-2 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV66957338; called by muse, mutect2, varscan2
- LRP6 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 92/417 reads (22%) | catalogued as rs1211813119, COSV99742863; called by muse, mutect2, varscan2
- MAGEA12 | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV100756859; called by muse, mutect2
- MRTFA | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs148866820; called by muse, mutect2, varscan2
- NRG1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV55149534; called by muse, mutect2, varscan2
- OR4D9 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs371435849; called by muse, varscan2
- PKHD1 | c.8776C>T p.R2926W | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs757650951, COSV61897318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCE1 | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV99594253; called by muse, mutect2, varscan2
- PNPLA8 | c.2240A>C p.K747T | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57555186; called by muse, mutect2, varscan2
- PRKCQ | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1231902533, COSV54110990; called by muse, mutect2, varscan2
- PTPN21 | c.2756C>A p.P919H | Missense Mutation (SNP) | VAF 103/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161715; called by muse, varscan2
- RHBDL3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs750572683, COSV52189577; called by muse, mutect2, varscan2
- ROBO2 | c.3229C>G p.P1077A | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); catalogued as rs201356083; called by muse, mutect2, varscan2
- SCN4A | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs557359808, COSV71125672, COSV71126789; called by muse, mutect2, varscan2
- SCN9A | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57627186; called by muse, mutect2, varscan2
- SEMA6B | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs547783583, COSV100014740; called by muse, mutect2, varscan2
- SOX5 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506445; called by muse, mutect2, varscan2
- SPAG17 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100309421, COSV60469856; called by muse, mutect2, varscan2
- SYNE1 | c.5504G>A p.R1835H (on ENST00000367255 / NM_182961.4; = p.R1842H on NM_033071.3) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as rs745746538, COSV55000536, COSV55019185; called by muse, mutect2, varscan2
- TGM4 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs768311392, COSV56093779; called by muse, mutect2, varscan2
- TLE1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64723808; called by muse, mutect2, varscan2
- TTN | c.33842C>T p.A11281V (on ENST00000591111; = p.A10354V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/336 reads (22%) | PolyPhen benign (0.001); catalogued as rs759232204, COSV60197702; called by muse, mutect2, varscan2
- URGCP | c.1621G>A p.G541S (on ENST00000453200 / NM_001077663.3; = p.G532S on NM_017920.4) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760516232, COSV56253537; called by muse, mutect2, varscan2
- ZNF614 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99571725; called by muse, varscan2
- ZNF621 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 96/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59459343; called by muse, mutect2, varscan2
- EDAR | c.653del p.P218Qfs*16 | Frame Shift Del (DEL) | VAF 87/399 reads (22%) | called by mutect2, pindel, varscan2
- PCDH9 | c.908_909del p.F303Cfs*4 | Frame Shift Del (DEL) | VAF 47/167 reads (28%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.1947_1977del p.Q649Hfs*259 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel
- AKAP6 | c.3235C>T p.L1079= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as rs767859144, COSV99799617; called by muse, mutect2, varscan2
- ARRB1 | c.861C>T p.L287= | Silent (SNP) | VAF 93/216 reads (43%) | catalogued as rs373519168; called by muse, mutect2, varscan2
- CHD5 | c.4635G>A p.S1545= | Silent (SNP) | VAF 148/272 reads (54%) | catalogued as rs140639533; called by muse, mutect2, varscan2
- DGAT1 | c.546G>C p.V182= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV60049502; called by muse, mutect2, varscan2
- DGAT2L6 | c.72C>A p.V24= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as COSV60718917; called by muse, mutect2, varscan2
- DIP2B | c.1458A>G p.K486= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as COSV56593296; called by muse, mutect2, varscan2
- DYTN | c.1470C>T p.D490= | Silent (SNP) | VAF 126/689 reads (18%) | catalogued as COSV71753140; called by muse, mutect2, varscan2
- IRS4 | c.3705C>T p.D1235= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV100929494; called by muse, mutect2
- KLHL38 | c.999C>T p.S333= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs780177938, COSV58089488; called by muse, mutect2, varscan2
- KRBA1 | c.2286G>A p.P762= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs376041143; called by muse, mutect2, varscan2
- KRT12 | c.1302C>T p.D434= | Silent (SNP) | VAF 110/260 reads (42%) | catalogued as COSV52431755; called by muse, varscan2
- MED24 | c.1314C>T p.V438= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs371817609; called by muse, mutect2, varscan2
- MYO7A | c.3165C>A p.P1055= | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as COSV101289090; called by muse, mutect2, varscan2
- NRXN2 | c.1758C>T p.G586= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as COSV55463333; called by muse, mutect2, varscan2
- PAPPA2 | c.4164G>T p.R1388= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100867746; called by muse, mutect2, varscan2
- REM2 | c.489G>T p.V163= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV57466141; called by muse, mutect2, varscan2
- SH3KBP1 | c.1650G>A p.P550= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs199899970, COSV65649527; called by muse, mutect2
- SLC12A5 | c.2568C>T p.H856= (on ENST00000454036 / NM_001134771.2; = p.H833= on NM_020708.5) | Silent (SNP) | VAF 196/494 reads (40%) | catalogued as rs371925559; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLN | c.54G>A p.T18= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs780287040, COSV100019448; called by mutect2, varscan2
- WIPF1 | c.231C>T p.G77= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs772302114, COSV55821139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF536 | c.1008C>T p.G336= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV62835842; called by muse, mutect2, varscan2
